Somatic mutation profile of tumor specimen TCGA-S9-A6WN-01A (aliquot TCGA-S9-A6WN-01A-12D-A33T-08) from TCGA case TCGA-S9-A6WN, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 38.2 years (13,961 days).
Specimen TCGA-S9-A6WN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1523f40-a9b9-48b1-b1ba-8f4e6364d340.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6WN-10A (Blood Derived Normal), aliquot TCGA-S9-A6WN-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1750b35d-8282-4a05-802a-ea664d02e4ad

The open-access MAF lists 37 somatic variants for this specimen: 33 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 25, Frame Shift Del 5, Silent 4, In Frame Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 39/187 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 38/168 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CKAP2 | c.328A>G p.T110A (on ENST00000378037 / NM_001098525.2; = p.T109A on NM_018204.5) | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99318342; called by muse, mutect2
- COL6A3 | c.6112G>A p.G2038R | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99799417; called by muse, mutect2, varscan2
- CR2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs749471642, COSV100889671; called by muse, mutect2, varscan2
- CSMD3 | c.5573T>C p.I1858T (on ENST00000297405 / NM_001363185.1; = p.I1754T on NM_052900.3) | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV99838513; called by muse, mutect2, varscan2
- CUL4B | c.1189T>C p.Y397H | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100340811; called by muse, mutect2, varscan2
- EGFR | c.2672A>G p.Y891C | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs987884612, COSV99292726; called by muse, mutect2, varscan2
- ENTPD7 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100978447; called by muse, mutect2, varscan2
- FCN1 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100878919; called by muse, mutect2, varscan2
- FRAS1 | c.7172G>A p.G2391D | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs778454575, COSV99353574; called by muse, mutect2, varscan2
- FTSJ1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.319); catalogued as COSV99191424; called by muse, mutect2, varscan2
- GRAMD1A | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1367884228; called by muse, mutect2
- HTR3A | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 116/516 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs918546404, COSV55471345, COSV55471669; called by muse, mutect2, varscan2
- MBD6 | c.2433_2434del p.C812Sfs*35 | Frame Shift Del (DEL) | VAF 22/135 reads (16%) | catalogued as rs1469558544; called by mutect2, pindel, varscan2
- MTREX | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57929094, COSV57929975, COSV57931651; called by muse, mutect2, varscan2
- MXRA5 | c.2740A>G p.I914V | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99477786; called by muse, mutect2
- N4BP2L2 | c.2641C>T p.P881S (on ENST00000674422; = p.P452S on NM_033111.4) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV100679136; called by muse, mutect2, varscan2
- OR9Q1 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as COSV100110153; called by muse, mutect2, varscan2
- PPP1R14D | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs373800458, COSV100146620; called by muse, mutect2, varscan2
- RAD9A | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100334986; called by muse, mutect2, varscan2
- SACM1L | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV101203776; called by muse, mutect2, varscan2
- SCN3A | c.4266T>G p.I1422M | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99327487; called by muse, mutect2, varscan2
- TMEM225 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66693012, COSV66694068; called by muse, mutect2, varscan2
- TTN | c.34909G>A p.V11637I (on ENST00000591111; = p.V10710I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | PolyPhen benign (0); catalogued as rs374394719; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- WDR55 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs749677633, COSV64226074; called by muse, mutect2, varscan2
- ZNF318 | c.6475_6478del p.N2159Lfs*51 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | catalogued as rs767339725; called by pindel, varscan2
- C2orf42 | c.668_670del p.F223del | In Frame Del (DEL) | VAF 40/259 reads (15%) | called by pindel, varscan2
- CDC42BPA | c.3740_3742del p.E1247del (on ENST00000334218 / NM_001366019.2; = p.E1234del on NM_003607.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 50/260 reads (19%) | called by pindel, varscan2
- FMR1 | c.822dup p.A275Sfs*2 | Frame Shift Ins (INS) | VAF 48/294 reads (16%) | called by mutect2, pindel, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | called by mutect2, varscan2
- TTN | c.62796del p.I20933* (on ENST00000591111; = p.I13509* on NM_003319.4) | Frame Shift Del (DEL) | VAF 32/157 reads (20%) | called by mutect2, pindel, varscan2
- ARRDC2 | c.294G>A p.T98= | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as rs779662264, COSV55843925; called by muse, mutect2, varscan2
- BBOF1 | c.1155A>G p.A385= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as COSV101223875; called by muse, mutect2, varscan2
- FITM1 | c.123A>G p.E41= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV99246323; called by muse, mutect2, varscan2
- ZMYM3 | c.1215C>T p.D405= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs751455760, COSV100078070; called by muse, mutect2, varscan2
